Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4895, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4895-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN'S NUCLEAR GRADE 4.

TUMOR EXTENDS INTO THE RENAL VEIN. (SEE COMMENT)

TUMOR EXTENDS INTO THE PERINEPHRIC ADIPOSE TISSUE.

TUMOR MEASURES 15.9 CM IN MAXIMUM DIMENSION.

Vascular, ureteral and soft tissue margins of resection free of tumor.

Adrenal gland, no tumor present.

COMMENT

The tumor focally extends into the intrarenal portion of the renal vein.

GROSS DESCRIPTION

A) LEFT KIDNEY AND ADRENAL GLAND - A nephrectomy specimen (20.0 x 18.5 x 7.8 cm, overall) including the left kidney (10.3 x 5.3 x 5.0 cm), attached ureter (13.0 cm in length and 0.5 cm in diameter) and the unremarkable adrenal gland (6.0 x 1.7 x 1.2 cm).

A well-demarcated tumor (15.9 x 9.0 x 10.0 cm) is located in the middle and lower portion of kidney. On cut surface, areas of cystic degeneration, hemorrhage, myxoid change, yellow solid areas are identified within the tumor. The tumor grossly involves the renal sinus adipose tissue and extends into the perinephric adipose tissue. The tumor focally extends into the intrarenal portion of the renal vein, possibly in one of the branches. The renal pelvis and the uninvolved kidney parenchyma are grossly unremarkable.

Representative sections of the tumor are submitted for possible electron microscopic studies.

INK CODE: Black-surface of renal capsule.

SECTION CODE: A1, section of ureter, renal vein, and renal artery margin; A2-A4, section of tumor involved renal vein and renal sinus; A5-A7, section of tumor and adjacent renal sinus; A8-A9, section of tumor closest to the renal capsule; A10-A12, section of tumor and perirenal adipose tissue; A13, section of tumor and normal adjacent renal parenchyma; A14-A26, representative sections of tumor from different areas; A27, normal renal parenchyma; A28, section of adrenal gland.

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-83123, T-B3000, M-00110

Source: NCI Genomic Data Commons file d8525f01-94ed-4762-93fa-6a0146338a73 (TCGA-CJ-4895.29DE2168-F05F-40B6-B57A-743F155DC9AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).